Somatic mutation profile of tumor specimen TCGA-06-2557-01A (aliquot TCGA-06-2557-01A-01D-1494-08) from TCGA case TCGA-06-2557, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 76.6 years (27,980 days).
Specimen TCGA-06-2557-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da769343-ce1e-4cbb-9d43-23a0a9666f47.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-2557-10A (Blood Derived Normal), aliquot TCGA-06-2557-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/885ab22d-4674-4647-a31d-9501d23d5828

The open-access MAF lists 51 somatic variants for this specimen: 37 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 13, Splice Region 2, Nonsense Mutation 2, 3'Flank 1, In Frame Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABI3BP | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777320308, COSV52541461; called by muse, mutect2, varscan2
- AKR1C1 | c.722T>A p.L241H | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66499407; called by muse, mutect2, varscan2
- APOBEC1 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as rs149648198; called by muse, mutect2, varscan2
- ATF7IP | c.1665A>T p.K555N | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53772197; called by muse, mutect2, varscan2
- ATP13A2 | c.2746G>A p.V916M | Missense Mutation (SNP) | VAF 127/245 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs768674400, COSV58700362; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- B3GALNT1 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as rs1479412243, COSV57580430; called by muse, mutect2, varscan2
- CCDC138 | c.396T>C p.V132= | Splice Region (SNP) | VAF 28/128 reads (22%) | catalogued as COSV54567907; called by muse, mutect2, varscan2
- CFAP100 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs768803759, COSV61503336; called by muse, mutect2, varscan2
- DICER1 | c.5581G>A p.E1861K | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58621646; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.312T>G p.C104W | Missense Mutation (SNP) | VAF 139/360 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.785); catalogued as COSV55930090; called by muse, mutect2, varscan2
- FAM136A | c.375G>A p.M125I | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.309); catalogued as COSV50682669; called by muse, mutect2, varscan2
- FIS1 | c.85T>A p.S29T | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV56191336; called by muse, mutect2, varscan2
- FKBP6 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.041); catalogued as rs782399413, COSV52720651; called by muse, varscan2
- FLRT1 | c.398A>G p.H133R | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55361616; called by muse, mutect2, varscan2
- HEATR3 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 53/84 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756461740, COSV53529690, COSV99590069; called by muse, mutect2
- IL27 | c.207G>A p.A69= | Splice Region (SNP) | VAF 17/66 reads (26%) | catalogued as rs764917281, COSV60490121; called by muse, mutect2, varscan2
- KBTBD2 | c.1370C>A p.T457N | Missense Mutation (SNP) | VAF 64/189 reads (34%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.981); catalogued as COSV58363590; called by muse, mutect2, varscan2
- KRT84 | c.151G>T p.G51C | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs776666279, COSV57772046; called by muse, mutect2, varscan2
- LENG1 | c.503_504del p.R168Tfs*5 | Frame Shift Del (DEL) | VAF 50/159 reads (31%) | catalogued as rs1568705319; called by pindel, varscan2
- LRP1B | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 36/116 reads (31%) | catalogued as COSV67230451; called by muse, mutect2, varscan2
- MAGEB6 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 45/59 reads (76%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.64); catalogued as rs775370255, COSV66872399; called by muse, mutect2, varscan2
- MOCS3 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV54866929; called by muse, mutect2
- MS4A3 | c.503C>T p.S168F | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as COSV53936466; called by muse, mutect2, varscan2
- MUC17 | c.4190C>T p.P1397L | Missense Mutation (SNP) | VAF 115/634 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.067); catalogued as rs141608296, COSV60280453; called by muse, mutect2, varscan2
- MYH13 | c.4396G>A p.E1466K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs775118096, COSV52833849; called by muse, mutect2, varscan2
- MYSM1 | c.2012A>G p.D671G | Missense Mutation (SNP) | VAF 57/99 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV68977598; called by muse, mutect2, varscan2
- NAPB | c.135T>A p.Y45* | Nonsense Mutation (SNP) | VAF 38/130 reads (29%) | catalogued as COSV65464641; called by muse, mutect2, varscan2
- NYAP1 | c.580C>A p.Q194K | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.095); catalogued as COSV55719886; called by muse, mutect2, varscan2
- PIK3C2B | c.3209A>C p.N1070T | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV65812062; called by muse, mutect2, varscan2
- PRDM15 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV54154087; called by muse, mutect2, varscan2
- SCN5A | c.3206C>T p.T1069M | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs199473187, CM055518, COSV61122207; ClinVar: likely benign / uncertain significance / not provided; called by muse, mutect2, varscan2
- SEMA3C | c.1582C>T p.R528W | Missense Mutation (SNP) | VAF 218/420 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs764684749, COSV54841672; called by muse, mutect2, varscan2
- SORCS3 | c.3314T>G p.V1105G | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63812730; called by muse, mutect2, varscan2
- TREML2 | c.140A>G p.K47R | Missense Mutation (SNP) | VAF 115/333 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV72439155; called by muse, mutect2, varscan2
- ZNF208 | c.1189T>C p.Y397H | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1242671182, COSV68109099; called by muse, mutect2, varscan2
- FANCM | c.4516C>T p.H1506Y | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TRPM4 | c.713_715dup p.G238_T239insS | In Frame Ins (INS) | VAF 17/50 reads (34%) | called by mutect2, pindel, varscan2
- AQP10 | c.213C>T p.Y71= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs1338492186, COSV61475362; called by muse, mutect2, varscan2
- ATG4D | c.396T>G p.P132= | Silent (SNP) | VAF 85/283 reads (30%) | catalogued as COSV58762829; called by muse, mutect2, varscan2
- CNKSR1 | c.186C>T p.G62= | Silent (SNP) | VAF 90/163 reads (55%) | catalogued as rs200570653; called by muse, mutect2, varscan2
- GPR65 | c.882C>T p.T294= | Silent (SNP) | VAF 16/123 reads (13%) | catalogued as rs751976148, COSV50863224; called by muse, mutect2, varscan2
- IKZF1 | c.1167C>T p.S389= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs1285428790, COSV58788209; called by muse, mutect2
- KAT5 | c.777C>T p.V259= | Silent (SNP) | VAF 111/266 reads (42%) | catalogued as rs771308702, COSV57729825; called by muse, mutect2, varscan2
- MADD | c.2532G>A p.G844= | Silent (SNP) | VAF 68/264 reads (26%) | catalogued as COSV60625156; called by muse, mutect2, varscan2
- OR5T3 | c.150C>A p.T50= | Silent (SNP) | VAF 66/169 reads (39%) | catalogued as COSV100282733, COSV57381062; called by muse, mutect2, varscan2
- POTEF | c.354C>T p.G118= | Silent (SNP) | VAF 48/136 reads (35%) | catalogued as rs747331658, COSV62541976; called by muse, mutect2, varscan2
- SGK1 | c.723C>T p.F241= | Silent (SNP) | VAF 120/208 reads (58%) | catalogued as rs201259463; called by muse, mutect2, varscan2
- TTF2 | c.57C>T p.V19= | Silent (SNP) | VAF 48/123 reads (39%) | catalogued as COSV65632797; called by muse, mutect2, varscan2
- ZNF391 | c.18G>A p.G6= | Silent (SNP) | VAF 51/136 reads (38%) | catalogued as COSV55123041; called by muse, mutect2, varscan2
- ZPLD1 | c.42G>A p.V14= (on ENST00000466937 / NM_001329788.1; = p.V30= on NM_175056.2) | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV60354096; called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73701163 C>T | 3'Flank (SNP) | VAF 33/127 reads (26%) | called by muse, mutect2, varscan2
